Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A7C4, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A7C4-01A (Primary Tumor).

PATHOLOGY REPORT
ENQUIRIES

Lab Reference
Date of Service

Tests requested by

HISTOPATHOLOGY REPORT

CLINICAL INFORMATION

Biopsy showed Grade II glioma.

MACROSCOPIC EXAMINATION

Labelled "Brain tumour".

Specimen consists of a soft pale grey irregular piece of tissue weighing 5.6 grammes and measuring 35x25x15mm. The cut surface is haemorrhagic and pale pink.

MICROSCOPIC DESCRIPTION

There is a diffuse proliferation of astrocytic cells with minor nuclear atypia and increased cellularity. However, there is no necrosis, obvious mitoses, or microvascular proliferation seen. There is <20% of gemistocytes seen. The overall appearances are in keeping with a diffuse astrocytoma, WHO grade II. I shall perform Ki-67 to confirm the mitotic rate, and a further report will follow.

agrees.

CONCLUSION

BRAIN TUMOUR

-- DIFFUSE ASTROCYTOMA, WHO GRADE II.

Additional Report.

Ki-67 shows immunoreactivity in astrocytic cells <4% - intensity 2-3+.

Reported by

ICD-O-3

Astrocytoma, grade II
9400/3

Site ^{C&F} Brain, supratentorial NOS
C71.0

path Brain NOS C71.9
20 9/25/13

W 7/10/13

ICD-O Discrepancy		☒
Qual/Synch/Specimen Primary Listed		☒

Tests ordered

Appointment	File	Phone
-------------	------	-------

Source: NCI Genomic Data Commons file 200107e6-22cd-4ba8-8810-bc918f39299f (TCGA-TM-A7C4.4097D689-A950-486D-9CDA-30C81E56722D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).